Gene-level copy-number profile of tumor specimen REBC-ACBL-TTP1-A from REBC case REBC-ACBL, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACBL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c20e717-9648-4ecc-a299-050bc6c7ea22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACBL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/1b5fb54a-66fc-4e51-9cd8-c93988cf0bb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,048; copy number 2: 55,742; copy number 3: 33; copy number 4: 18; copy number 5: 74.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 74 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 4 genes, copy number 5 (within-gene range 2–5): AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr3:196,739,857–196,832,647, 1 gene, copy number 5 (within-gene range 2–5): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 5: RNU6-42P.
- chr7:142,760,415–142,763,943, 1 gene, copy number 5 (within-gene range 2–5): PRSS3P1.
- chr14:22,112,347–22,513,998, 66 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
